Somatic mutation profile of tumor specimen TARGET-10-PARBCW-09A (aliquot TARGET-10-PARBCW-09A-01D) from TARGET case TARGET-10-PARBCW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,264 days).
Specimen TARGET-10-PARBCW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5703ba06-8116-466b-9031-c9324fd2dd66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBCW-10A (Blood Derived Normal), aliquot TARGET-10-PARBCW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fb13b16-8d35-4a8a-8195-509ffa7f8542

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Splice Site 1, 3'UTR 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs1386770293, COSV57049403; called by muse, mutect2, varscan2
- ADAMTS18 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs149189203; called by muse, mutect2, varscan2
- AIDA | c.180+1G>A p.X60_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as rs763614952; called by muse, varscan2
- GREB1L | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs559234950; called by muse, mutect2, varscan2
- IL7R | c.727_728insCCTTGTGGGCCCCGTT p.L243Pfs*32 | Frame Shift Ins (INS) | VAF 19/165 reads (12%) | catalogued as COSV57406244, COSV57406538, COSV57408312, COSV57408637, COSV57411199, COSV57411469, COSV57413100, COSV99073420; called by mutect2, pindel*
- ITPR2 | c.7169G>T p.R2390L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67274152; called by muse, mutect2
- KCNK9 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1471072625, COSV57278542, COSV57284128; called by muse, mutect2, varscan2
- KDR | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55771235; called by muse, mutect2, varscan2
- PCDHGC4 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); catalogued as rs753979217, COSV99341489; called by muse, mutect2, varscan2
- PPARGC1B | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs189353551, COSV58533455; called by muse, mutect2, varscan2
- SH2B1 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs779441545, COSV59460709; called by muse, mutect2, varscan2
- STIM1 | c.227A>C p.D76A | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56160059, COSV56160187; called by muse, mutect2, varscan2
- PHF3 | c.14A>T p.D5V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RUNX1 | c.190C>T p.R64C (on ENST00000344691 / NM_001001890.3; = p.R91C on NM_001754.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CNTN5 | c.114G>A p.K38= | Silent (SNP) | VAF 7/200 reads (4%) | catalogued as rs1223103991, COSV54335485; called by muse, mutect2
- GPR78 | c.1032G>A p.A344= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs774004850; called by muse, mutect2, varscan2
- RXYLT1 | c.276G>A p.T92= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- SLC18A3 | c.1077C>T p.Y359= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV60320553; called by muse, mutect2
- PPP2R1B | chr11:111737527 T>C | 3'Flank (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2
- SLC39A8 | c.*102G>A | 3'UTR (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
